Surgical pathology report (de-identified scan), TCGA case TCGA-FL-A1YQ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Hawaii - Normal Study, specimen TCGA-FL-A1YQ-11A (Solid Tissue Normal).

[page 1 of 2]
Surgical Pathology Report

Patient Name: [REDACTED]
Med. Rec. #: [REDACTED]
DOB: [REDACTED]
Gender: F
Physician(s): [REDACTED]
cc: [REDACTED]

Client: [REDACTED]
Location: [REDACTED]

Accession #: [REDACTED]
Taken: [REDACTED]
Received: [REDACTED]
Reported: [REDACTED]

History/Clinical Dx: Pelvic mass

Postoperative Dx: Pending pathology

ICD-0-3 not applicable.

Normal path from non-cancer patient.

fw 11/11/11

Specimen(s) Received:

- A: Right ovary and tube
- B: Left ovary and tube
- C: Uterus and cervix
- D: Left pelvic lymph nodes

DIAGNOSIS:

A. Right ovary and tube:

- 1. Mature cystic teratoma
- 2. Fallopian tube with no pathologic change

B. Left ovary and tube:

Tube and ovary with no pathologic change

C. Uterus and cervix:

Cervix:
Endometrium:
Myometrium:

Chronic inflammation
Proliferative phase
Leiomyoma, intramural

D. Left pelvic lymph nodes:

Two lymph nodes with no evidence of malignancy

Intraoperative Consultation:

A. Frozen section: Benign

Gross Description

- A. Submitted as "left ovary and tube and dermoid cyst" is a partially collapsed cystic structure measuring 6.5 x 5.5 x 2.4 cm in greatest dimension. The opened cyst has a slightly granular tan-grey inner lining. There is abundant sebaceous material present. There is also a fallopian tube, which measures 5.0 cm in length and shows evidence of previous ligation. Representative sections are submitted in four cassettes.

Regulatory Statement: The following statement may be applicable to some of the reagents/antibodies used in developing the above report. This test was developed and its performance characteristics determined by [REDACTED] for [REDACTED] research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

[page 2 of 2]
Surgical Pathology Report

- B. Submitted as "right ovary and tube" is a tube with attached ovary weighing 12 grams. The ovary measures 2.2 x 1.0 x 0.8 cm in greatest dimension and is grossly unremarkable. The tube measures 4.0 cm in length and up to 0.5 cm in diameter. It shows evidence of previous ligation. Representative sections are submitted in two cassettes.
- C. Submitted as "uterus and cervix" is a previously opened uterus and cervix which weighing 125 grams and measures 8.5 x 5.0 x 3.5 cm in greatest dimension. The serosal surface is smooth. The ectocervical mucosa is smooth. The endocervical canal contains no gross lesions. The endometrial cavity is lined by tan mucosa measuring up to 0.2 cm in thickness. The myometrium measures up to 2.3 cm in thickness. There is a single well circumscribed white-tan nodule, which measures 0.9 cm in diameter.

KEY TO CASSETTES:

C1-C2 - Cervix
C3-C5 - Endo/myometrium
C6 - Myometrial nodule

- D. Submitted as "left pelvic lymph nodes" is a single fragment of fatty tissue weighing 9 grams. Possible lymph node tissue is submitted intact in four cassettes.

Microscopic Description

A-D. The microscopic findings support the above diagnoses.

Source: NCI Genomic Data Commons file 98a2f8a7-d9f9-4438-a745-1a79cf11df79 (TCGA-FL-A1YQ.A183E852-81EF-413C-85F0-122FB8F22DE2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).